Somatic mutation profile of tumor specimen ALCH-B1UU-TTP1-A (aliquot ALCH-B1UU-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1UU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.3 years (26,786 days).
Specimen ALCH-B1UU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 013840e9-e15b-4565-bdf8-c08d5b43a218.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1UU-NB1-A (Blood Derived Normal), aliquot ALCH-B1UU-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acf76c71-4f05-48ce-86bf-63ef8468c2e5

The open-access MAF lists 192 somatic variants for this specimen: 133 protein-altering or splice-affecting, 32 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 32, Intron 11, Nonsense Mutation 10, RNA 9, Splice Site 5, 5'UTR 3, 5'Flank 2, Frame Shift Del 2, 3'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 179/486 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 34/373 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2
- AC006059.2 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs1233067033; called by muse, mutect2
- ACTC1 | c.919A>T p.M307L | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); catalogued as CM040002; called by muse, mutect2
- ANKRD33B | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs780887396; called by muse, mutect2, varscan2
- APOA5 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs760422549; called by muse, mutect2
- BEND4 | c.1134C>G p.D378E | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.001); catalogued as COSV72469292; called by muse, mutect2, varscan2
- BICC1 | c.82G>C p.V28L | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65856123; called by muse, mutect2
- C10orf67 | c.1583A>G p.E528G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.022); catalogued as rs1401618232; called by muse, mutect2, varscan2
- C20orf85 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1568817532; called by muse, mutect2
- CDC42BPB | c.3418G>T p.G1140C | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV63476439; called by muse, mutect2, varscan2
- CELF1 | c.706C>T p.Q236* (on ENST00000358597 / NM_001376422.1; = p.Q232* on NM_006560.4 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/430 reads (7%) | catalogued as COSV100137051; called by muse, mutect2
- CNTNAP2 | c.2780C>A p.A927D | Missense Mutation (SNP) | VAF 61/648 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV62267786; called by muse, mutect2
- CSMD3 | c.5996del p.G1999Efs*20 (on ENST00000297405 / NM_001363185.1; = p.G1895Efs*20 on NM_052900.3) | Frame Shift Del (DEL) | VAF 33/311 reads (11%) | catalogued as rs1449334722, COSV52211083, COSV52286393; called by mutect2, pindel
- DNAH11 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528684070; called by muse, mutect2
- DSCAML1 | c.3478C>A p.L1160M (on ENST00000321322; = p.L1100M on NM_020693.4) | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as COSV58384497; called by muse, mutect2, varscan2
- FAM47A | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV100649974, COSV60495260; called by muse, mutect2, varscan2
- FAT1 | c.7960G>A p.V2654I | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs779677759, COSV71673658; called by muse, mutect2
- FBN2 | c.8167C>A p.P2723T | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.856); catalogued as rs143401228; called by muse, mutect2, varscan2
- FLI1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1355289095, COSV61379989; called by muse, mutect2, varscan2
- FZD3 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs1264012492; called by muse, mutect2
- GCSAML | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV63577066, COSV63578013; called by muse, mutect2, varscan2
- GLG1 | c.1339del p.E447Rfs*19 | Frame Shift Del (DEL) | VAF 51/422 reads (12%) | catalogued as rs1567477383; called by mutect2, pindel, varscan2
- HAND1 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV99039261; called by muse, mutect2
- HDAC9 | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV67784937; called by muse, mutect2
- HTR6 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs200873870; called by muse, mutect2
- IGHV3-66 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.099); catalogued as rs377538322; called by muse, mutect2, varscan2
- IGSF1 | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV63837785; called by muse, mutect2, varscan2
- IL31RA | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.145); catalogued as COSV51682238; called by muse, mutect2, varscan2
- KCNC3 | c.577C>G p.R193G | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65388835; called by muse, mutect2
- LHX8 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53961098; called by muse, mutect2, varscan2
- LHX8 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs766574879, COSV53958502; called by muse, mutect2
- MAP7 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.349); catalogued as rs757742259; called by muse, mutect2, varscan2
- MRPL42 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs775316745, COSV100696640; called by muse, mutect2
- NLRP5 | c.1954C>A p.L652M | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1317068811; called by muse, mutect2, varscan2
- NTNG2 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs1307949338; called by muse, mutect2
- OR2V1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs377463886; called by muse, mutect2, varscan2
- PCARE | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs757131197, COSV59054261; called by muse, mutect2, varscan2
- PCCA | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV66189273; called by muse, mutect2, varscan2
- PCDH10 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 26/449 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52090362, COSV52104097; called by muse, mutect2
- PCDH18 | c.2521G>T p.G841W | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61267653; called by muse, mutect2
- PCDHB12 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 11/263 reads (4%) | catalogued as COSV99506626; called by muse, mutect2
- PTPRCAP | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV57050659; called by muse, mutect2, varscan2
- PWWP3A | c.869C>T p.S290L (on ENST00000627377; = p.S289L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1298281521, COSV60903447; called by muse, mutect2, varscan2
- RIMS2 | c.3658G>T p.G1220* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as rs1384694928; called by muse, mutect2
- RIMS2 | c.3659G>T p.G1220V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (1); catalogued as COSV99158744; called by muse, mutect2
- SELENBP1 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs774554029, COSV64373005, COSV64373295; called by muse, mutect2, varscan2
- SLC30A8 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69973602; called by muse, mutect2, varscan2
- SPON2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 51/360 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs1319361577, COSV52055317; called by muse, mutect2, varscan2
- SYT13 | c.936G>C p.K312N | Missense Mutation (SNP) | VAF 32/495 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV50072893; called by muse, mutect2
- TAF1L | c.2428G>T p.V810F | Missense Mutation (SNP) | VAF 136/646 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99643966; called by muse, mutect2, varscan2
- TBC1D16 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.389); catalogued as rs372358351; called by muse, mutect2
- TENM2 | c.3430G>T p.V1144L (on ENST00000518659 / NM_001122679.2; = p.V912L on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs549901644; called by muse, mutect2, varscan2
- TNFSF11 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV53477913; called by muse, mutect2, varscan2
- TRIM51 | c.1052G>A p.W351* | Nonsense Mutation (SNP) | VAF 45/447 reads (10%) | catalogued as rs1274045532; called by muse, mutect2, varscan2
- TTYH2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146608677; called by muse, mutect2
- USP2 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs779431454; called by muse, mutect2
- VWA5B1 | c.2968+1G>C p.X990_splice (on ENST00000375079; = p.X985_splice on NM_001039500.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/260 reads (10%) | catalogued as rs1484885583; called by muse, mutect2, varscan2
- ZNF420 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV58495559; called by muse, mutect2
- ABCA2 | c.966C>A p.D322E (on ENST00000614293; = p.D292E on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ACKR1 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 45/376 reads (12%) | called by muse, mutect2, varscan2
- ALPK2 | c.1843C>G p.L615V | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2
- ARHGAP17 | c.1486G>C p.E496Q | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2
- ATF7IP | c.2176G>A p.V726I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2
- ATRN | c.4214T>C p.I1405T | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- BPIFA3 | c.537-8C>A | Splice Region (SNP) | VAF 12/380 reads (3%) | called by muse, mutect2
- CACNG3 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CD300A | c.775-1G>T p.X259_splice | Splice Site (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- CDCA7L | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLIP2 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2
- CRTC1 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.084); called by muse, mutect2
- DNAJB6 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- EPG5 | c.5756A>G p.K1919R | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2
- FCN3 | c.398T>C p.F133S | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GJC2 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- GNAL | c.217G>A p.E73K (on ENST00000269162 / NM_001142339.3; = p.E150K on NM_182978.4) | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2
- GOPC | c.612A>T p.R204S | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- HDAC5 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- HUWE1 | c.6928C>G p.Q2310E | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.028); called by muse, mutect2
- JPH2 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- KCNB2 | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF1A | c.3756G>T p.W1252C (on ENST00000320389 / NM_001379639.1; = p.W1244C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF1A | c.3755G>T p.W1252L (on ENST00000320389 / NM_001379639.1; = p.W1244L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KMT2C | c.13543G>T p.E4515* | Nonsense Mutation (SNP) | VAF 51/496 reads (10%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.286A>T p.S96C (on ENST00000418998 / NM_001377303.1; = p.S74C on NM_032107.5) | Missense Mutation (SNP) | VAF 43/681 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); called by muse, mutect2
- LRP1B | c.6221A>T p.N2074I | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2
- LYAR | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.158); called by muse, mutect2
- MAP4K2 | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- MKRN3 | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MYF6 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); called by muse, mutect2
- NCR1 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPY1R | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2
- NRBF2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10A6 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- OR5A1 | c.345C>A p.C115* | Nonsense Mutation (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- OR5A1 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2
- OR5L1 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR6N2 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- OR8H1 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- OTUD4 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.54); called by muse, mutect2, varscan2
- PAX9 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PCDHA3 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLP1 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNA4 | c.3038A>T p.E1013V | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PNISR | c.2221A>T p.K741* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- PPARGC1A | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.891); called by muse, mutect2
- PTPN21 | c.2945G>C p.W982S | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIMS1 | c.2810C>A p.T937K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RINT1 | c.690-1G>T p.X230_splice | Splice Site (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- RYR1 | c.11542A>G p.R3848G | Missense Mutation (SNP) | VAF 65/611 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLC16A7 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SLC28A1 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- SLC35F1 | c.847+1G>T p.X283_splice | Splice Site (SNP) | VAF 47/248 reads (19%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX11 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); called by muse, mutect2
- SPHKAP | c.3594G>T p.M1198I | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- STS | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE2 | c.6404+1G>A p.X2135_splice | Splice Site (SNP) | VAF 24/585 reads (4%) | called by muse, mutect2
- TBC1D9B | c.457G>C p.G153R | Missense Mutation (SNP) | VAF 51/514 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TDRD3 | c.1862A>C p.Q621P | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TENT5D | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TNFRSF25 | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); called by muse, mutect2
- TRBV24-1 | c.148A>G p.R50G | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM42 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 85/508 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPM5 | c.3469G>T p.G1157W | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2
- TTF2 | c.2766A>T p.R922S | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- UBE2QL1 | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- VCAN | c.833C>A p.A278E | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XKRX | c.467A>T p.H156L | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZIC1 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ZNF384 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF800 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- ZSWIM3 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.261); called by muse, mutect2
- ACSS3 | c.228C>T p.F76= | Silent (SNP) | VAF 38/769 reads (5%) | catalogued as COSV99698878; called by muse, mutect2
- ADAM19 | c.1971G>A p.K657= | Silent (SNP) | VAF 23/331 reads (7%) | called by muse, mutect2
- ALPK2 | c.1353C>G p.L451= | Silent (SNP) | VAF 17/346 reads (5%) | called by muse, mutect2
- ALX3 | c.663G>A p.R221= | Silent (SNP) | VAF 28/481 reads (6%) | catalogued as rs750158911; called by muse, mutect2
- C3AR1 | c.417C>A p.A139= | Silent (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- CLCN4 | c.2139G>T p.V713= | Silent (SNP) | VAF 34/261 reads (13%) | called by muse, mutect2, varscan2
- COL14A1 | c.3657G>T p.V1219= | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- COL16A1 | c.2007A>T p.P669= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- DCLK1 | c.259C>T p.L87= | Silent (SNP) | VAF 44/406 reads (11%) | catalogued as COSV55195587; called by muse, mutect2, varscan2
- DDR2 | c.2229C>T p.I743= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- FHOD3 | c.108C>T p.D36= | Silent (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- GFI1B | c.192G>A p.P64= | Silent (SNP) | VAF 94/582 reads (16%) | catalogued as rs778912632, COSV59745541; called by muse, mutect2, varscan2
- GFPT1 | c.504C>T p.T168= | Silent (SNP) | VAF 18/231 reads (8%) | called by muse, mutect2
- GJB3 | c.96G>C p.R32= | Silent (SNP) | VAF 30/495 reads (6%) | called by muse, mutect2
- GNG13 | c.195C>T p.T65= | Silent (SNP) | VAF 20/432 reads (5%) | called by muse, mutect2
- GRIK4 | c.456G>T p.G152= | Silent (SNP) | VAF 66/403 reads (16%) | called by muse, mutect2, varscan2
- H4C2 | c.231C>G p.A77= | Silent (SNP) | VAF 49/273 reads (18%) | called by muse, mutect2, varscan2
- HMX3 | c.864G>T p.A288= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as COSV63501442; called by muse, mutect2, varscan2
- ITIH6 | c.3621C>T p.F1207= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs1419533772, COSV54487220; called by muse, mutect2, varscan2
- KCNB2 | c.1329C>A p.A443= | Silent (SNP) | VAF 14/268 reads (5%) | catalogued as COSV73053268; called by muse, mutect2
- LKAAEAR1 | c.495G>A p.A165= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
- NCOR2 | c.3138C>T p.P1046= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- NKX2-2 | c.559C>A p.R187= | Silent (SNP) | VAF 30/233 reads (13%) | catalogued as COSV65820171; called by muse, mutect2, varscan2
- OR2F2 | c.897G>T p.G299= | Silent (SNP) | VAF 24/145 reads (17%) | called by muse, mutect2, varscan2
- PALLD | c.2139A>T p.L713= | Silent (SNP) | VAF 47/479 reads (10%) | called by muse, mutect2
- PCOLCE | c.396G>A p.T132= | Silent (SNP) | VAF 74/453 reads (16%) | called by muse, mutect2, varscan2
- RRP36 | c.687G>A p.L229= | Silent (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- RYR2 | c.7632C>T p.L2544= | Silent (SNP) | VAF 20/396 reads (5%) | called by muse, mutect2
- SNAPC4 | c.1002G>T p.L334= | Silent (SNP) | VAF 31/219 reads (14%) | catalogued as rs1454750260; called by muse, mutect2, varscan2
- TMEM33 | c.33G>A p.G11= | Silent (SNP) | VAF 40/325 reads (12%) | catalogued as rs1020200019; called by muse, mutect2, varscan2
- ZFHX4 | c.4050G>A p.P1350= | Silent (SNP) | VAF 22/205 reads (11%) | catalogued as rs749725605, COSV50737398, COSV99266767; called by muse, mutect2, varscan2
- ZNF492 | c.951C>A p.A317= | Silent (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- AC136604.1 | n.445C>A | RNA (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- ADAM6 | n.1488G>C | RNA (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- AGBL4 | c.34+28533G>A | Intron (SNP) | VAF 17/542 reads (3%) | called by muse, mutect2
- ALMS1P1 | n.974G>T | RNA (SNP) | VAF 30/344 reads (9%) | called by muse, mutect2
- AP000769.3 | chr11:65504773 G>T | 5'Flank (SNP) | VAF 17/357 reads (5%) | called by muse, mutect2
- BOD1P2 | n.250A>C | RNA (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- CCDC74A | c.251-47T>C | Intron (SNP) | VAF 46/548 reads (8%) | called by muse, mutect2
- CHCHD2P9 | n.284C>A | RNA (SNP) | VAF 84/691 reads (12%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812040 del C | 3'Flank (DEL) | VAF 18/164 reads (11%) | called by mutect2, varscan2
- DAZAP1 | c.1049-969G>T | Intron (SNP) | VAF 8/230 reads (3%) | called by muse, mutect2
- DCHS2 | n.4853G>A | RNA (SNP) | VAF 12/198 reads (6%) | catalogued as rs1201138792; called by muse, mutect2
- FGFR1 | c.-41G>A | 5'UTR (SNP) | VAF 12/294 reads (4%) | catalogued as rs1280460663, COSV100248421, COSV58343272; called by muse, mutect2
- GAD1 | c.1185-26C>G | Intron (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- GFRA1 | c.-49C>A | 5'UTR (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- HMGB1P1 | n.304T>A | RNA (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- MGAM | c.4619-8706C>G | Intron (SNP) | VAF 28/497 reads (6%) | called by muse, mutect2
- MIRLET7F1 | n.2C>G | RNA (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- NUDT9P1 | n.578G>T | RNA (SNP) | VAF 24/300 reads (8%) | catalogued as rs1335271130; called by muse, mutect2
- PEX5L | c.22-1518C>G | Intron (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559297 C>A | 5'Flank (SNP) | VAF 76/822 reads (9%) | called by muse, mutect2
- SARDH | c.915+4195C>T | Intron (SNP) | VAF 14/184 reads (8%) | catalogued as rs1198704254; called by muse, mutect2
- SARDH | c.915+4193T>C | Intron (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- SERGEF | c.60+112G>C | Intron (SNP) | VAF 23/262 reads (9%) | called by muse, mutect2
- SOX18 | c.-36C>A | 5'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- TEX35 | c.*484G>C | 3'UTR (SNP) | VAF 12/296 reads (4%) | catalogued as rs1359061875; called by muse, mutect2
- TRIB3 | c.-1+1409C>G | Intron (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- ZNF23 | c.143-824C>T | Intron (SNP) | VAF 12/180 reads (7%) | catalogued as rs1013480175; called by muse, mutect2
